Somatic mutation profile of tumor specimen CPT008930 (aliquot CPT008930-0002) from CPTAC case 01BR009, project CPTAC-2 (Breast). Tissue or organ of origin: Breast, NOS.
Specimen CPT008930: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4edb617f-3dd1-4fc4-9f0e-0ebed6dc3ac3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CPT009156 (Solid Tissue Normal), aliquot CPT009156-0001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/835bc5d1-34d0-4682-96e4-2340b25c0843

The open-access MAF lists 29 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Intron 6, Silent 3, RNA 2, In Frame Del 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARD14 | c.1192G>C p.E398Q | Missense Mutation (SNP) | VAF 41/353 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); catalogued as rs139740020; called by muse, mutect2, varscan2
- CHRDL1 | c.21C>G p.I7M (on ENST00000372045; = p.I13M on NM_145234.4) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.11); catalogued as COSV54328099; called by muse, mutect2, varscan2
- CX3CL1 | c.710A>G p.E237G | Missense Mutation (SNP) | VAF 90/315 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.42); catalogued as rs200554957; called by muse, mutect2, varscan2
- DGCR2 | c.1592C>G p.A531G | Missense Mutation (SNP) | VAF 51/512 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.02); catalogued as rs892461700; called by muse, mutect2, varscan2
- GOLGA8J | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 47/456 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as rs779836595; called by muse, mutect2, varscan2
- GPR158 | c.2023C>T p.R675* | Nonsense Mutation (SNP) | VAF 63/211 reads (30%) | catalogued as rs1189568483; called by muse, mutect2, varscan2
- SQLE | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 23/206 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs773317153; called by mutect2, varscan2
- ANKRD30B | c.1799T>G p.F600C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- CCDC138 | c.1672C>A p.L558I | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GTPBP2 | c.197G>C p.G66A | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LCMT1 | c.713G>C p.G238A | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- NLE1 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.999); called by muse, mutect2
- OSR1 | c.20_49del p.P7_L16del | In Frame Del (DEL) | VAF 47/230 reads (20%) | called by mutect2, pindel, varscan2
- PPIL3 | c.450G>C p.K150N (on ENST00000392283 / NM_130906.3; = p.K154N on NM_032472.4) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RBPJL | c.372G>T p.M124I | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- TBPL2 | c.20C>G p.P7R | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- TRPC4 | c.348G>T p.L116F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR5L1 | c.429G>A p.E143= | Silent (SNP) | VAF 9/224 reads (4%) | called by muse, mutect2
- REV1 | c.2925T>C p.N975= | Silent (SNP) | VAF 8/131 reads (6%) | catalogued as rs1214610116; called by muse, mutect2
- TCF7 | c.1302T>G p.L434= | Silent (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- ABCA8 | c.1789-332G>T | Intron (SNP) | VAF 6/74 reads (8%) | catalogued as COSV52201886; called by muse, mutect2
- CEP126 | c.507-2000T>C | Intron (SNP) | VAF 20/430 reads (5%) | called by muse, mutect2
- HHLA1 | c.140-1079C>G | Intron (SNP) | VAF 34/267 reads (13%) | called by muse, mutect2, varscan2
- IGKV6D-41 | c.-12C>A | 5'UTR (SNP) | VAF 19/137 reads (14%) | called by muse, mutect2, varscan2
- LINC01169 | n.375G>C | RNA (SNP) | VAF 31/188 reads (16%) | called by muse, mutect2, varscan2
- MAGED1 | c.1739-18C>G | Intron (SNP) | VAF 8/135 reads (6%) | called by muse, mutect2
- MCM3AP | c.4290+1936A>G | Intron (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- MYADML | n.1116G>A | RNA (SNP) | VAF 33/167 reads (20%) | catalogued as rs1162853437; called by muse, mutect2, varscan2
- SRD5A3 | c.365-9G>A | Intron (SNP) | VAF 18/321 reads (6%) | called by muse, mutect2
